Gene-level copy-number profile of tumor specimen TCGA-IB-7886-01A from TCGA case TCGA-IB-7886, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 80.3 years (29,319 days).
Specimen TCGA-IB-7886-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PAAD.2fe39c41-2396-4ac4-b14e-94f163cc3f15.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IB-7886-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0421170b-3731-4ac5-a70c-c3f0dfcca578

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,176; copy number 2: 26,163; copy number 3: 26,262; copy number 4: 5,828; copy number 6: 63; copy number 7: 265; copy number 13: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IB-7886-01A-11D-2153-01): tumor purity 0.51, ploidy 2.63, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:25,351,418–25,520,854, 7 genes (within-gene range 0–2): LRP5L, AL022324.3, AL008721.1, IGLVIVOR22-1, CRYBB2P1, MIR6817, AL008721.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 316 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:19,582,317–32,993,754, 254 genes, copy number 7–13 (broad region; genes not listed).
- chr18:22,088,060–24,986,980, 62 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,176. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
